CCDI case PBCDTZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/83633661-1674-4fd7-903f-d73871106e82

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Germinoma: ICD-O-3 morphology code: 9064/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.5 years (4,577 days).

Biospecimens (2 samples)
- Sample 0DPX3H: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPX3U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
